Somatic mutation profile of tumor specimen TCGA-J9-A52C-01A (aliquot TCGA-J9-A52C-01A-11D-A26M-08) from TCGA case TCGA-J9-A52C, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.4 years (20,966 days).
Specimen TCGA-J9-A52C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19fc1f3f-89ac-4312-b5a8-12d83c3b8a60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A52C-10A (Blood Derived Normal), aliquot TCGA-J9-A52C-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b537b51-e26f-44f6-820f-d0e80df1341b

The open-access MAF lists 621 somatic variants for this specimen: 442 protein-altering or splice-affecting, 165 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 330, Silent 165, Frame Shift Del 64, Nonsense Mutation 19, In Frame Del 10, Frame Shift Ins 10, Intron 7, Splice Region 5, RNA 3, Splice Site 3, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- GNPTAB | c.2693del p.K898Sfs*13 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as rs281864999, CD090839; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 7/39 reads (18%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL4 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs201202045; called by muse, mutect2, varscan2
- AADAT | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV61787041; called by muse, mutect2, varscan2
- ABCA13 | c.12854T>G p.L4285R | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68945138; called by muse, mutect2, varscan2
- ABCB5 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.318); catalogued as COSV68855071; called by muse, mutect2, varscan2
- ABR | c.1993C>T p.R665W (on ENST00000302538 / NM_021962.5; = p.R628W on NM_001092.5) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1273391318, COSV52144013, COSV52144933; called by muse, mutect2, varscan2
- ACKR3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs774901344, COSV56021147; called by muse, mutect2, varscan2
- ADAMTS18 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765623782, COSV51403298; called by muse, mutect2, varscan2
- ADAMTS6 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs148384415; called by muse, mutect2, varscan2
- ADAMTSL1 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52813130; called by muse, mutect2, varscan2
- ADGRF4 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs145102054; called by muse, mutect2, varscan2
- AGO3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55792366; called by muse, mutect2, varscan2
- AGRN | c.5497G>A p.V1833I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs377622440; called by muse, mutect2
- AKAP12 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs200318359; called by muse, mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- ANAPC5 | c.2044A>C p.K682Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV55842067; called by muse, mutect2, varscan2
- ANK1 | c.5251G>A p.E1751K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs142163190, COSV55877901; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | catalogued as rs370637835; called by mutect2, varscan2
- ANKFN1 | c.258dup p.H87Tfs*2 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs1322720501; called by mutect2, varscan2
- ANKRD11 | c.7735C>T p.R2579C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567537413, COSV56358396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1G2 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV55337826; called by muse, mutect2, varscan2
- AP3M1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs190136804, COSV62330952; called by muse, mutect2, varscan2
- AQP4 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67218386; called by muse, mutect2, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs759782104; called by mutect2, varscan2
- ARAF | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs754803899, COSV51691990; called by mutect2, varscan2
- ARHGAP25 | c.1402A>G p.N468D (on ENST00000409202 / NM_001007231.3; = p.N460D on NM_014882.3) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.36); catalogued as COSV54900690; called by muse, mutect2, varscan2
- ARHGAP30 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs1296781780, COSV63512301; called by muse, mutect2, varscan2
- ARHGEF19 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54615962; called by muse, mutect2, varscan2
- ARHGEF6 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV51689082; called by muse, mutect2, varscan2
- ASAP1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs745406996, COSV63044358, COSV63051230; called by muse, mutect2, varscan2
- ASPG | c.1075del p.E359Rfs*2 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as COSV101496412; called by mutect2, pindel, varscan2
- ATP2B3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs781988092, COSV54843602; called by muse, mutect2, varscan2
- ATP2B3 | c.2189G>A p.C730Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV54843635; called by muse, mutect2, varscan2
- ATP8B1 | c.3728C>T p.A1243V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs764485724, COSV52174131; called by muse, mutect2, varscan2
- AURKB | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs749454960, COSV60244122; called by muse, mutect2, varscan2
- B3GNT7 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1462869560, COSV55006141; called by muse, mutect2, varscan2
- B4GALNT1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs765536804, COSV57542116; ClinVar: uncertain significance; called by muse, mutect2
- B4GALT1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs750518389, COSV65707789; called by mutect2, varscan2
- B4GALT2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.646); catalogued as rs202199424, COSV58843171; called by muse, mutect2, varscan2
- BEST3 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200668742, COSV58299957; called by muse, mutect2, varscan2
- BICD1 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV55677199; called by muse, mutect2, varscan2
- BIRC6 | c.4168C>T p.R1390C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1335001376, COSV70197450; called by muse, mutect2
- BIVM-ERCC5 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs750156480, COSV63244587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP5 | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63702157; called by muse, mutect2
- BMP7 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1339607526, COSV67780193; called by muse, mutect2
- BOD1L1 | c.4874A>T p.D1625V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs760579857, COSV50008819; called by muse, mutect2, varscan2
- BPNT1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs369548050; called by mutect2, varscan2
- BRPF3 | c.2689C>T p.R897C | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs367563122; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD7 | c.3025T>C p.Y1009H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.085); catalogued as rs1340838541, COSV58284631; called by muse, mutect2, varscan2
- C1orf174 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV59496255; called by muse, mutect2, varscan2
- C2CD2L | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1267182209, COSV60883847; called by muse, mutect2, varscan2
- C8B | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs747647469, COSV64776503; called by muse, mutect2, varscan2
- CACHD1 | c.3223G>A p.V1075I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs371572990; called by muse, mutect2, varscan2
- CACHD1 | c.3551G>A p.R1184H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs371669378; called by mutect2, varscan2
- CACNA1A | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349147232, COSV64194153; called by muse, mutect2, varscan2
- CACNG8 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as rs1034925737, COSV54414296; called by muse, mutect2
- CADPS2 | c.902T>C p.M301T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777278440, COSV57356652; called by muse, mutect2
- CALHM1 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs775666606, COSV53294535, COSV53297358; called by muse, mutect2, varscan2
- CAPN15 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756826201, COSV54835075; called by mutect2, varscan2
- CCDC114 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV59556003; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC57 | c.1997G>A p.R666K | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100492656, COSV58934405; called by muse, mutect2, varscan2
- CCDC74A | c.776del p.P259Qfs*2 | Frame Shift Del (DEL) | VAF 19/162 reads (12%) | catalogued as rs772061983; called by mutect2, varscan2
- CCDC88B | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs200509973, COSV57265515; called by muse, mutect2, varscan2
- CCDC92 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs202226542; called by muse, varscan2
- CCKAR | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs200308893, COSV55160173; called by muse, mutect2, varscan2
- CCL17 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV54664638; called by muse, mutect2, varscan2
- CCR7 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs947333410, COSV55849053; called by muse, mutect2, varscan2
- CDC25A | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56770196; called by muse, mutect2, varscan2
- CDC42EP1 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs748248737, COSV50756112; called by muse, mutect2, varscan2
- CDH16 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs1165275272, COSV55335574, COSV55340120; called by muse, mutect2, varscan2
- CEACAM5 | c.1802dup p.D602Rfs*19 | Frame Shift Ins (INS) | VAF 22/139 reads (16%) | catalogued as rs782698410; called by mutect2, varscan2
- CFAP53 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs778228003, COSV68351597; called by muse, mutect2
- CFH | c.2861_2863del p.E954del | In Frame Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs774399812; called by pindel, varscan2
- CHRNA4 | c.955dup p.L319Pfs*59 | Frame Shift Ins (INS) | VAF 11/97 reads (11%) | catalogued as rs770462797; called by mutect2, pindel, varscan2
- CHRNE | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as COSV53417363; called by muse, mutect2, varscan2
- CHST5 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs756913516, COSV60338282; called by muse, mutect2, varscan2
- CLCNKB | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.858); catalogued as rs192283350, CM082571, COSV65160167; called by muse, mutect2
- CLDN15 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56191083, COSV56191209; called by muse, mutect2
- CNOT1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs371890421, COSV100408635; called by muse, mutect2, varscan2
- CNTF | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747429064, COSV60157113; called by muse, mutect2, varscan2
- COBL | c.2973G>T p.Q991H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV54342217; called by muse, mutect2, varscan2
- COL6A1 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV62612456; called by muse, mutect2, varscan2
- COPB1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1006041516, COSV51447564; called by muse, mutect2, varscan2
- CPNE6 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs746384542, COSV53743387, COSV53745791; called by muse, mutect2, varscan2
- CPT1C | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs753309074, COSV54918161; called by muse, mutect2, varscan2
- CREBBP | c.5147C>T p.T1716M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52118838; called by muse, mutect2, varscan2
- CRTC2 | c.1800C>A p.F600L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57841052, COSV57841860; called by muse, mutect2, varscan2
- CSMD2 | c.9745C>T p.R3249W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs760982366, COSV53897840; called by muse, mutect2, varscan2
- CTC1 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.442); catalogued as COSV59852725; called by muse, mutect2
- CUBN | c.5323C>T p.R1775W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1276708; called by muse, mutect2, varscan2
- CUX1 | c.655G>A p.D219N (on ENST00000292535 / NM_181552.4; = p.D230N on NM_001913.5) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs782816778, COSV52891835; called by muse, mutect2
- CUX1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371099197, COSV52895310; called by muse, mutect2, varscan2
- CXXC1 | c.1939A>G p.T647A | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV53273636; called by muse, mutect2, varscan2
- CYB5R1 | c.689A>C p.Q230P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV61851250; called by muse, mutect2, varscan2
- CYP27C1 | c.552G>A p.T184= | Splice Region (SNP) | VAF 13/142 reads (9%) | catalogued as rs138626696; called by muse, mutect2
- CYP2B6 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 61/361 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs781365650, COSV60699093; called by muse, mutect2, varscan2
- CYP4X1 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs151115170; called by muse, mutect2, varscan2
- CYTH2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs760826182, COSV57309040; called by muse, mutect2, varscan2
- DBH | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV55040283; called by muse, mutect2, varscan2
- DCC | c.3742G>A p.V1248M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs201242417, COSV101473359, COSV71429727; called by muse, mutect2, varscan2
- DCLRE1A | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.232); catalogued as rs775411239, COSV63748426; called by muse, mutect2, varscan2
- DDN | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.012); catalogued as rs771843519, COSV60292064; called by muse, mutect2, varscan2
- DDR2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376303676; called by muse, mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 6/24 reads (25%) | catalogued as rs755280697; called by mutect2, pindel
- DGCR8 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs757595892, COSV61226165; called by muse, mutect2, varscan2
- DIDO1 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56617746; called by muse, mutect2, varscan2
- DLGAP1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1344032507, COSV59785214; called by muse, mutect2
- DMXL1 | c.4681C>T p.R1561* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs780539211, COSV60708338; called by mutect2, varscan2
- DNAH17 | c.4081C>T p.R1361C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200427893; called by muse, mutect2
- DNAH5 | c.5718G>A p.M1906I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1324133724, COSV54215396; called by muse, mutect2
- DOT1L | c.4337C>T p.P1446L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs752426227, COSV67108892; called by muse, mutect2, varscan2
- DPP3 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV64756364; called by muse, mutect2, varscan2
- DPP4 | c.1294T>C p.Y432H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62105961; called by muse, mutect2, varscan2
- DSCAML1 | c.2449G>A p.V817I (on ENST00000321322; = p.V757I on NM_020693.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs761947783, COSV58387011; called by muse, mutect2, varscan2
- EDC3 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.621); catalogued as rs1482616970, COSV59339636; called by muse, mutect2, varscan2
- EFNB3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs750774945, COSV56833152, COSV99872752; called by muse, mutect2, varscan2
- EFNB3 | c.836del p.G279Vfs*15 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs1241382696; called by mutect2, pindel, varscan2
- EIF3D | c.1464G>T p.W488C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53399399; called by muse, mutect2, varscan2
- ELMO1 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209023342, COSV60300078, COSV60300321; called by muse, mutect2, varscan2
- EME2 | c.1116T>A p.D372E | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as COSV51599649; called by muse, mutect2, varscan2
- EOMES | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs772872800, COSV55411819; called by muse, mutect2
- EPG5 | c.4597G>A p.A1533T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs374899586; called by mutect2, varscan2
- EPHB2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs767048571, COSV65861338; called by muse, mutect2
- EPPK1 | c.3278C>T p.T1093M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as rs372633695; called by muse, mutect2, varscan2
- ERBB3 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as rs1488014391, COSV57249659; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs780487406; called by mutect2, pindel
- ERMARD | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs770631548, COSV64649841; called by muse, mutect2, varscan2
- ESF1 | c.1930dup p.R644Kfs*11 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | catalogued as rs1568712741; called by mutect2, varscan2
- ESPL1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs567786268, COSV57758461; called by muse, mutect2, varscan2
- EWSR1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100130981, COSV58422614; called by muse, mutect2, varscan2
- EXTL1 | c.1459A>G p.T487A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65332493; called by muse, mutect2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAM207A | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs576306304, COSV52420117; called by muse, mutect2, varscan2
- FAM53A | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100356885; called by muse, mutect2, varscan2
- FAM98A | c.522del p.K174Nfs*2 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs1237814873; called by mutect2, varscan2
- FAT4 | c.13264T>C p.Y4422H | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV58678228; called by muse, mutect2, varscan2
- FGF23 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs1026101992, COSV52975575; called by muse, mutect2, varscan2
- FHOD3 | c.3988G>A p.A1330T (on ENST00000359247 / NM_001281739.3; = p.A1347T on NM_025135.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1440823844, COSV57169445; called by muse, mutect2, varscan2
- FMN2 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs576376829, COSV60425346, COSV60434479; called by muse, mutect2, varscan2
- FOXB2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277482340, COSV65022737; called by muse, mutect2, varscan2
- FOXD2 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as rs1429672672, COSV58303835; called by muse, mutect2, varscan2
- FZD1 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs745620349, COSV55309724; called by muse, mutect2, varscan2
- GABBR2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1168707085, COSV52299269; called by muse, mutect2, varscan2
- GAK | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs894810912, COSV58503750; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs548474277; called by mutect2, varscan2
- GCN1 | c.4529C>T p.S1510L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs750993380, COSV56105782; called by muse, mutect2, varscan2
- GFOD1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64954498; called by muse, mutect2, varscan2
- GFOD2 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs910195161, COSV52057286; called by muse, mutect2, varscan2
- GFUS | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71254217, COSV71254327; called by muse, mutect2, varscan2
- GGCT | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.031); catalogued as rs765582824, COSV50040779; called by muse, mutect2, varscan2
- GKN2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV61031052; called by muse, mutect2, varscan2
- GLB1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs553660803, COSV56567000; called by mutect2, varscan2
- GLIS3 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs537966660, COSV60925919; called by muse, mutect2, varscan2
- GMPR | c.292-2A>G p.X98_splice | Splice Site (SNP) | VAF 8/73 reads (11%) | catalogued as COSV52472778; called by muse, mutect2, varscan2
- GPR149 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.369); catalogued as rs764527641, COSV67665625, COSV67666258, COSV67666659; called by muse, mutect2, varscan2
- GPRASP1 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs776134683, COSV64355220; called by muse, mutect2, varscan2
- GRAMD2A | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV59033203; called by muse, mutect2
- GRIK4 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751433660, COSV70801307; called by muse, mutect2, varscan2
- GRIN3B | c.2052G>A p.K684= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as rs1436267052, COSV52259403; called by muse, mutect2, varscan2
- H2AC12 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.092); catalogued as rs1032409513, COSV63616822, COSV63617521; called by muse, mutect2, varscan2
- HADHB | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs770736746, COSV58545513; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 24/155 reads (15%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HECA | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760164332, COSV62768949; called by muse, mutect2, varscan2
- HLCS | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV60792359; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs761272507; called by mutect2, varscan2
- HOXD10 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV50898834; called by muse, mutect2, varscan2
- HS6ST1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs765246934, COSV52127558; called by muse, mutect2, varscan2
- HTR1A | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV60500357; called by muse, mutect2, varscan2
- HTR6 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs376637765; called by muse, mutect2, varscan2
- HTRA4 | c.966+2T>C p.X322_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV56758925; called by muse, mutect2
- IGHMBP2 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as rs972425138, CM034524, COSV54821463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGSF1 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs1408040076, COSV63836010; called by muse, mutect2, varscan2
- IL1RAP | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs763802602, COSV50759217; called by muse, mutect2, varscan2
- INTS1 | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV67176958; called by muse, mutect2, varscan2
- ITPRIPL2 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV67347471; called by muse, mutect2, varscan2
- JADE2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768632846, COSV50913230; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.862A>G p.S288G | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV59823203; called by muse, mutect2, varscan2
- KAAG1 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as rs1270753724, COSV51239610; called by muse, mutect2, varscan2
- KDM3B | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as rs1433657420, COSV58689591, COSV58691959; called by muse, mutect2, varscan2
- KIAA1549L | c.3397A>G p.T1133A (on ENST00000321505; = p.T1430A on NM_012194.3) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.807); catalogued as rs1417640477, COSV55771576; called by muse, mutect2, varscan2
- KIF21B | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373134245; called by muse, mutect2, varscan2
- KLF5 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV66613982; called by muse, mutect2, varscan2
- KLK15 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757337160, COSV56826432; called by muse, mutect2, varscan2
- KPNA1 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | catalogued as COSV60268354; called by muse, mutect2, varscan2
- KPNA5 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV62651836; called by muse, mutect2
- KRT80 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs565212849, COSV57548306; called by muse, mutect2, varscan2
- KRT80 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766339844, COSV57548325; called by muse, mutect2
- LAMB2 | c.3662C>T p.T1221M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as rs770277410, COSV59732180; called by muse, mutect2, varscan2
- LAMB2 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747800713, COSV59732190; called by muse, mutect2, varscan2
- LBR | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as rs765875442, COSV55288281; called by muse, mutect2, varscan2
- LCT | c.1675G>A p.G559S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs147029208, COSV51545501; called by muse, mutect2, varscan2
- LGALS14 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs768482478, COSV100648497, COSV62372110; called by muse, mutect2, varscan2
- LHX2 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV65318032; called by muse, mutect2, varscan2
- LHX4 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs773975101, COSV55374358; called by muse, mutect2, varscan2
- LHX6 | c.959A>G p.Y320C (on ENST00000373755 / NM_001242334.2; = p.Y349C on NM_014368.5) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61344282; called by muse, mutect2, varscan2
- LMNA | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs775159300, COSV61542351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1 | c.8078G>A p.R2693H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs199834508, COSV54506328; called by muse, mutect2, varscan2
- LRP4 | c.1022G>T p.S341I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV66134990; called by muse, mutect2, varscan2
- LRP8 | c.1678G>T p.G560W | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60097402; called by muse, mutect2, varscan2
- LRRC10 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs201257055, COSV64060229, COSV64060517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC29 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs778879029, COSV58526893; called by muse, mutect2, varscan2
- LRRC41 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.815); catalogued as rs28363251; called by muse, mutect2, varscan2
- LRRC41 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1164186138, COSV58439487; called by muse, mutect2, varscan2
- LRRC8D | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs910629309, COSV61578355; called by muse, mutect2
- MAGEB2 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV66780554; called by muse, mutect2
- MAP3K11 | c.2205C>T p.R735= | Splice Region (SNP) | VAF 3/13 reads (23%) | catalogued as rs768273388, COSV58419013; called by muse, mutect2
- MAP3K13 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs188669013, COSV53986166, COSV53996158; called by muse, mutect2, varscan2
- MBD1 | c.1508C>T p.A503V (on ENST00000269468 / NM_001323950.1; = p.A447V on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs555450900, COSV53999572; called by muse, mutect2, varscan2
- MED1 | c.4450G>A p.D1484N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1290658800, COSV56123577; called by muse, mutect2, varscan2
- MFGE8 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 16/127 reads (13%) | catalogued as rs141213799, COSV51555726; called by muse, mutect2, varscan2
- MFSD2A | c.1097G>A p.R366Q (on ENST00000372809 / NM_001136493.3; = p.R353Q on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs540449746, COSV65685296; called by muse, mutect2, varscan2
- MMRN2 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV64400584; called by muse, mutect2
- MRNIP | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52972610; called by muse, mutect2, varscan2
- MRTFA | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1226700433, COSV62932417; called by muse, mutect2, varscan2
- MTCL1 | c.1846G>A p.A616T (on ENST00000306329 / NM_001378206.1; = p.A256T on NM_015210.4) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757292748, COSV60403859; called by muse, mutect2, varscan2
- MUTYH | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs767747402, COSV58343848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.1725A>C p.E575D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62449104; called by muse, mutect2, varscan2
- MYO5A | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs916981993, COSV62558390; called by muse, mutect2, varscan2
- NAE1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as rs1317080797, COSV51975453; called by muse, mutect2
- NDST1 | c.1309T>C p.Y437H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV55785902; called by muse, mutect2, varscan2
- NFASC | c.167G>A p.R56H (on ENST00000339876 / NM_001378329.1; = p.R50H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs747820571, COSV58362684; called by muse, mutect2, varscan2
- NLRP8 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs199475833, COSV52585175; called by muse, mutect2, varscan2
- NT5C2 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs774448444, COSV58415584; called by muse, mutect2, varscan2
- NTRK3 | c.2330C>T p.T777M (on ENST00000360948 / NM_001012338.2; = p.T763M on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs754383313, COSV62297959, COSV62319177; called by muse, mutect2, varscan2
- NYNRIN | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV66841771; called by muse, mutect2, varscan2
- OLFML2A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.911); catalogued as rs750373492, COSV59160793; called by muse, mutect2, varscan2
- OR4N2 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV60050730; called by muse, mutect2, varscan2
- OR5P2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147652902; called by muse, mutect2
- OR9G1 | c.445T>C p.C149R | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV56449623; called by muse, mutect2
- ORC2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs1223475964, COSV52237879, COSV52240743; called by muse, mutect2, varscan2
- OSBPL6 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770933596, COSV51914366; called by muse, mutect2, varscan2
- PARP10 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57297327; called by muse, mutect2
- PARP15 | c.1205C>T p.S402L (on ENST00000464300 / NM_001113523.3; = p.S168L on NM_152615.2) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747548533, COSV59972053; called by muse, mutect2, varscan2
- PATZ1 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.818); catalogued as rs766392086, COSV56743314; called by muse, mutect2, varscan2
- PCDH9 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV60539583; called by muse, mutect2, varscan2
- PCDHAC2 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs782055086, COSV53843864; called by muse, mutect2, varscan2
- PCDHB7 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50759847; called by muse, mutect2, varscan2
- PCDHB9 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53379089; called by muse, mutect2, varscan2
- PCDHGA5 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs538468873, COSV53922882; called by mutect2, varscan2
- PCDHGA7 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.082); catalogued as rs1015626472, COSV53922923; called by muse, mutect2, varscan2
- PCDHGB6 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1445467116, COSV53922935; called by muse, mutect2
- PCGF2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1270907226; called by muse, mutect2, varscan2
- PCNX2 | c.4192C>T p.Q1398* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV50790186; called by muse, mutect2
- PCOLCE | c.545del p.P182Rfs*19 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs766866388; called by mutect2, pindel
- PDE12 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489366621, COSV60818340; called by muse, mutect2, varscan2
- PDGFRB | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55803171; called by muse, mutect2, varscan2
- PDZD8 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs749127376, COSV57824433; called by muse, mutect2, varscan2
- PDZRN3 | c.3116C>T p.T1039M | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55195294; called by muse, mutect2, varscan2
- PGBD4 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs768046561, COSV56627332; called by mutect2, varscan2
- PHF1 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs754941553, COSV53379806; called by muse, mutect2, varscan2
- PHKB | c.1262A>T p.K421I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54518263; called by muse, mutect2
- PHYHIPL | c.183A>G p.I61M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65848313; called by muse, mutect2, varscan2
- PIGB | c.529dup p.C177Lfs*79 | Frame Shift Ins (INS) | VAF 12/82 reads (15%) | catalogued as rs1356026422; called by mutect2, varscan2
- PIGQ | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752387143, COSV50312668; called by muse, mutect2, varscan2
- PIK3R1 | c.1079C>T p.A360V (on ENST00000521381 / NM_181523.3; = p.A90V on NM_181504.4) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57127766; called by muse, mutect2
- PITRM1 | c.3077C>T p.P1026L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs1383095699, COSV56528899, COSV99829451; called by muse, mutect2
- PKD1L1 | c.2297A>G p.Y766C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56961642; called by muse, varscan2
- PLCZ1 | c.91T>A p.L31I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.194); catalogued as COSV56850953; called by muse, mutect2, varscan2
- PMFBP1 | c.2689C>T p.Q897* (on ENST00000537465; = p.Q892* on NM_031293.3) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV52822428; called by muse, mutect2, varscan2
- POLL | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760809916, COSV54574261; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPM1D | c.474G>A p.A158= | Splice Region (SNP) | VAF 26/166 reads (16%) | catalogued as rs766503109, COSV59955032, COSV59957323; called by muse, mutect2, varscan2
- PPP1R13L | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as rs767692178, COSV62908202; called by muse, mutect2, varscan2
- PRKAR1A | c.1094T>G p.I365S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56836238; called by muse, mutect2, varscan2
- PRKCA | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV52581720; called by muse, mutect2, varscan2
- PRKCH | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as rs1401498476, COSV60647101; called by muse, mutect2, varscan2
- PRKCZ | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66066593; called by muse, mutect2, varscan2
- PRKX | c.239T>C p.M80T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV53323086, COSV99468596; called by muse, mutect2, varscan2
- PRM2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs200756329, COSV54112988, COSV54113189; called by muse, mutect2, varscan2
- PRPF4B | c.1059_1061del p.R353del | In Frame Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs750668576; called by pindel, varscan2
- PSMD4 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1239968019, COSV64393206; called by muse, mutect2, varscan2
- PSRC1 | c.785G>A p.R262H (on ENST00000409138 / NM_001363309.1; = p.R232H on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs765011270, COSV64021146; called by muse, mutect2, varscan2
- PTK2 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as rs756149985, COSV61784039; called by muse, mutect2, varscan2
- PTPN14 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1204270584, COSV65283011; called by muse, mutect2, varscan2
- PTPRU | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs761766129, COSV60525094; called by muse, mutect2, varscan2
- PXYLP1 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs369570856; called by muse, mutect2, varscan2
- PYM1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs887433411, COSV56811740; called by muse, mutect2, varscan2
- QTRT1 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV51550803; called by muse, mutect2, varscan2
- RAPGEF1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.961); catalogued as rs1216895774, COSV64698799; called by muse, mutect2
- RCOR3 | c.746T>C p.L249S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV65365348; called by muse, mutect2
- RGS9 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs761061220, COSV52224279; called by muse, mutect2, varscan2
- RHBDF1 | c.2470G>A p.V824I | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs369772748, COSV51954431, COSV51955702; called by muse, mutect2, varscan2
- RHBDL3 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as rs1295767153, COSV52185277; called by muse, varscan2
- RHOC | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV53517131; called by muse, mutect2
- RIC1 | c.1046+1G>A p.X349_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52607810; called by muse, mutect2, varscan2
- RLBP1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs1393804387, CM1312892, COSV51527701; called by muse, mutect2, varscan2
- RNF213 | c.8834G>A p.R2945H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs76918558, COSV60389944; called by muse, mutect2
- RNF213 | c.14123G>A p.R4708H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs773098626, COSV60389684; called by muse, mutect2, varscan2
- RNF213 | c.15274C>T p.R5092W | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs773939686, COSV60394144; called by muse, mutect2, varscan2
- RP1L1 | c.3661G>A p.G1221S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs754082146, COSV66753517; called by mutect2, varscan2
- RPAP1 | c.3089C>T p.S1030L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs769819778, COSV58537482; called by muse, mutect2, varscan2
- RTKN | c.902C>T p.A301V (on ENST00000272430 / NM_001015055.2; = p.A288V on NM_033046.2) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51962251; called by muse, mutect2
- RTN4RL2 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58651571; called by muse, mutect2, varscan2
- SACS | c.8450C>T p.T2817M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs371652968; called by mutect2, varscan2
- SASH1 | c.2983C>T p.R995C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs749914751, COSV66560411; called by muse, mutect2, varscan2
- SBF1 | c.5006C>T p.P1669L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as rs376409019; called by muse, mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3F | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs200910175, COSV50028953; called by muse, mutect2
- SEMA4F | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs779262858, COSV60282749; called by muse, varscan2
- SH3BP4 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs758870615, COSV60642077; called by muse, mutect2, varscan2
- SIGLEC9 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs759377738, COSV51583448; called by muse, mutect2, varscan2
- SLC10A3 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV54835982; called by muse, mutect2
- SLC12A4 | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50452473; called by muse, mutect2, varscan2
- SLC12A4 | c.1536_1538del p.F513del | In Frame Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs776364033; called by pindel, varscan2
- SLC25A22 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs778299128, COSV57192657; called by muse, mutect2
- SLC25A53 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs370922777, COSV62458774; called by muse, mutect2, varscan2
- SLC2A13 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs1296094273, COSV55114350, COSV55121049; called by muse, mutect2, varscan2
- SLC41A1 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs773375948, COSV65650334; called by muse, mutect2, varscan2
- SLC6A17 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776517148, COSV58991757; called by muse, mutect2, varscan2
- SMOC1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs749505789, COSV62760239; called by muse, mutect2, varscan2
- SMPD4 | c.2021C>T p.A674V (on ENST00000409031 / NM_017951.4; = p.A645V on NM_017751.4) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.457); catalogued as rs747953273, COSV60079395; called by muse, mutect2, varscan2
- SNRNP200 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV60488568; called by muse, mutect2, varscan2
- SNX1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1388900478, COSV56037836; called by muse, mutect2, varscan2
- SPATA31E1 | c.3466G>A p.V1156M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV57790554; called by muse, mutect2, varscan2
- SPSB4 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs200129730, COSV100141227, COSV60146317; called by muse, mutect2, varscan2
- SPTB | c.5779G>A p.E1927K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.243); catalogued as rs1232851302, COSV67630720; called by muse, mutect2, varscan2
- SPTBN2 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1005600223, COSV59449776; called by muse, mutect2, varscan2
- SSH2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs759004141, COSV52169243; called by muse, mutect2, varscan2
- STAB2 | c.6412C>T p.H2138Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66337075; called by muse, mutect2, varscan2
- STAT3 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM163855, COSV52884882; called by muse, mutect2, varscan2
- STK40 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755810424, COSV63735087; called by muse, mutect2, varscan2
- STRIP2 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753949992, COSV50803706; called by muse, mutect2, varscan2
- SV2B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs748998104, COSV57699202; called by muse, mutect2, varscan2
- SYBU | c.1942G>A p.V648M (on ENST00000276646 / NM_001099754.2; = p.V647M on NM_017786.6) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as rs566837139, COSV52616055; called by muse, mutect2, varscan2
- SYNE1 | c.11246C>T p.T3749M (on ENST00000367255 / NM_182961.4; = p.T3734M on NM_033071.3) | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs778034684, COSV54946190; called by muse, mutect2, varscan2
- TAF1C | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754084058, COSV58985618; called by muse, mutect2, varscan2
- TANC1 | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230137835, COSV55085735; called by muse, mutect2
- TAP1 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62754109; called by muse, mutect2, varscan2
- TASOR | c.4256A>G p.N1419S (on ENST00000355628 / NM_001365636.2; = p.N1043S on NM_015224.3) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV58302717; called by muse, mutect2, varscan2
- TBATA | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs200788611, COSV54717122; called by muse, mutect2, varscan2
- TBX15 | c.1379G>A p.S460N (on ENST00000369429 / NM_001330677.2; = p.S354N on NM_152380.3) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.07); catalogued as COSV52869487; called by muse, mutect2
- TCEA3 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs747251283, COSV71531873; called by muse, mutect2, varscan2
- TET3 | c.5027C>T p.T1676M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69641724; called by muse, mutect2, varscan2
- TEX14 | c.1169C>T p.A390V (on ENST00000240361 / NM_001201457.2; = p.A384V on NM_031272.5) | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs761691069, COSV53614334; called by muse, mutect2, varscan2
- TEX33 | c.764del p.N255Mfs*3 (on ENST00000381821 / NM_001163857.2; = p.N170Mfs*3 on NM_178552.4) | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs773740291; called by mutect2, pindel, varscan2
- TG | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs985329037, COSV55071080; called by muse, mutect2, varscan2
- THSD7A | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV70262866; called by muse, mutect2, varscan2
- TMCO4 | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs367840733; called by muse, mutect2, varscan2
- TMEM130 | c.1250G>A p.R417H (on ENST00000416379 / NM_001134450.2; = p.R405H on NM_152913.3) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781947519, COSV59558435; called by muse, mutect2, varscan2
- TMEM161A | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.612); catalogued as COSV99365377; called by muse, mutect2, varscan2
- TMEM201 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV61051147; called by muse, mutect2, varscan2
- TMEM255B | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs371183456; called by muse, mutect2, varscan2
- TNFRSF11B | c.1002A>G p.I334M | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs758824253, COSV52070153, COSV52071990; called by muse, mutect2, varscan2
- TOP2A | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs548652478, COSV70732374; called by muse, mutect2, varscan2
- TP53BP1 | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV55498789; called by muse, mutect2, varscan2
- TRAPPC6B | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs763991701, COSV57527557; called by muse, mutect2
- TTBK1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52489723; called by muse, mutect2, varscan2
- TTC16 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV60160319; called by muse, mutect2, varscan2
- TTI1 | c.2479G>A p.V827I | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.053); catalogued as COSV65061104; called by muse, mutect2, varscan2
- TTLL5 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs762742540, COSV54029067; called by muse, mutect2, varscan2
- TUBA1A | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as COSV55497210; called by muse, mutect2, varscan2
- TUBB4A | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51153017; called by muse, mutect2, varscan2
- UBN1 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); catalogued as rs767469919, COSV52167085; called by muse, mutect2, varscan2
- UFL1 | c.1978del p.R660Gfs*17 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as rs750472217; called by mutect2, pindel, varscan2
- UGGT2 | c.2923A>G p.T975A | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV65073557; called by muse, mutect2
- UNC5B | c.1091A>T p.N364I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV58975859; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs760213136; called by mutect2, varscan2
- UPF1 | c.3104G>A p.R1035H (on ENST00000599848 / NM_001297549.2; = p.R1024H on NM_002911.4) | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs1234132463, COSV53194989; called by muse, mutect2, varscan2
- USP19 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs748917627; called by muse, mutect2, varscan2
- USP35 | c.3039C>G p.F1013L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); catalogued as COSV60866944; called by muse, mutect2, varscan2
- USP6 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs201324904, COSV51479073, COSV51483836; called by muse, mutect2, varscan2
- VEGFA | c.457C>T p.R153* (on ENST00000523873 / NM_001171623.1; = p.R333* on NM_003376.6) | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs769957944, COSV57878119; called by muse, mutect2, varscan2
- VILL | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52183441; called by muse, mutect2, varscan2
- VPS51 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs774498013, COSV54206687; called by muse, mutect2, varscan2
- VPS52 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 28/150 reads (19%) | catalogued as rs765485457, COSV71403442; called by muse, mutect2, varscan2
- VWF | c.2072del p.P691Qfs*50 | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | catalogued as rs267607309, CX1310905; ClinVar: not provided; called by mutect2, pindel, varscan2
- WAPL | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1443840857, COSV53933683; called by muse, mutect2, varscan2
- WDR6 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.561); catalogued as rs190640692, COSV58244463; called by muse, mutect2, varscan2
- WFS1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760631912, COSV56988321; called by muse, mutect2, varscan2
- WWC1 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.146); catalogued as rs368353585, COSV54656652; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | catalogued as rs762052135; called by mutect2, varscan2
- XYLT1 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.322); catalogued as rs769835425, COSV104372359, COSV54481361; called by muse, mutect2, varscan2
- ZBTB17 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1188980893, COSV65268935; called by muse, mutect2, varscan2
- ZFHX3 | c.6770T>C p.L2257S | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51713748; called by muse, mutect2, varscan2
- ZFYVE26 | c.5971G>A p.V1991I | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs758072287, COSV61326511; called by muse, mutect2, varscan2
- ZMYND12 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs767153865, COSV65341779; called by muse, mutect2, varscan2
- ZNF180 | c.1177A>G p.S393G | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55420479; called by muse, mutect2
- ZNF30 | c.1478_1479del p.F493* | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs1446213403; called by mutect2, pindel, varscan2
- ZNF385D | c.11_12del p.I4Nfs*30 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | catalogued as rs868651961; called by mutect2, pindel, varscan2
- ZNF419 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | catalogued as rs765373810, COSV55658629; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs780189754; called by mutect2, pindel
- ZNF521 | c.1781A>T p.Y594F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.952); catalogued as COSV64124838; called by muse, mutect2, varscan2
- ZNF563 | c.622del p.W208Gfs*62 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | catalogued as rs751446191, COSV53370335; called by mutect2, varscan2
- ZNF660 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV59548770; called by muse, mutect2, varscan2
- ZNF700 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV54311658; called by muse, mutect2, varscan2
- ZSWIM8 | c.3595C>T p.R1199C (on ENST00000605216 / NM_001242487.2; = p.R1204C on NM_015037.3) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs200608670, COSV55212874; called by muse, mutect2, varscan2
- ABCF1 | c.789dup p.Q264Tfs*5 | Frame Shift Ins (INS) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- AGL | c.2123_2125del p.L708del | In Frame Del (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.3594dup p.E1199Rfs*5 | Frame Shift Ins (INS) | VAF 16/111 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD20A1 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, varscan2
- ARHGAP35 | c.2575del p.Y859Ifs*28 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | called by mutect2, varscan2
- BCHE | c.218dup p.P74Afs*9 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- CCDC92 | c.385_387del p.K129del | In Frame Del (DEL) | VAF 35/193 reads (18%) | called by pindel, varscan2
- CD93 | c.943del p.A315Pfs*273 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- DHX38 | c.3309del p.T1104Pfs*14 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- FBXO34 | c.1550del p.G517Vfs*68 | Frame Shift Del (DEL) | VAF 29/162 reads (18%) | called by mutect2, pindel, varscan2
- FLG | c.8852G>A p.G2951D | Missense Mutation (SNP) | VAF 23/466 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- FREM2 | c.2767_2769del p.H923del | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- HECTD4 | c.7503_7504del p.P2502Sfs*24 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- KDM6A | c.2717del p.N906Mfs*31 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, varscan2
- KLHL7 | c.1191_1192del p.Y398Ffs*3 (on ENST00000339077 / NM_001031710.3; = p.Y350Ffs*3 on NM_018846.5) | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel
- KMT2D | c.4111_4112del p.D1371Qfs*60 | Frame Shift Del (DEL) | VAF 27/157 reads (17%) | called by mutect2, pindel, varscan2
- MORC3 | c.1953del p.E652Kfs*8 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- MYH4 | c.1799del p.N600Tfs*5 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- NCOR1 | c.4177_4179del p.N1393del | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2
- NR1I2 | c.1270del p.L424Sfs*59 | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- NWD1 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- POLR1A | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- POLR2A | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARA | c.1288del p.M430Wfs*8 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by pindel, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- RERE | c.248del p.K83Sfs*12 | Frame Shift Del (DEL) | VAF 41/205 reads (20%) | called by mutect2, varscan2
- RGS2 | c.190del p.S64Afs*25 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- RLF | c.5019del p.K1673Nfs*11 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- RPL3 | c.382_384del p.K128del | In Frame Del (DEL) | VAF 10/84 reads (12%) | called by pindel, varscan2
- SACS | c.9081del p.F3027Lfs*25 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SACS | c.4982_4984del p.S1661del | In Frame Del (DEL) | VAF 8/48 reads (17%) | called by pindel, varscan2
- SAMD11 | c.1679_1680del p.E560Vfs*180 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2
- SIGLEC6 | c.534del p.I179Sfs*39 | Frame Shift Del (DEL) | VAF 17/117 reads (15%) | called by mutect2, pindel, varscan2
- TACC2 | c.6446del p.P2149Qfs*2 (on ENST00000334433; = p.P227Qfs*2 on NM_006997.4) | Frame Shift Del (DEL) | VAF 28/237 reads (12%) | called by mutect2, pindel, varscan2
- TBC1D26 | c.201_202del p.R68Tfs*5 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- TBX4 | c.1329dup p.T444Hfs*29 | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, pindel
- TMED8 | c.789_790del p.G264Lfs*30 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by pindel, varscan2
- TMEM50A | c.99del p.F33Lfs*8 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- TNFRSF11A | c.328del p.R110Gfs*73 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- TRAP1 | c.609_619del p.G204Sfs*6 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- TRIM35 | c.1222del p.D408Tfs*4 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- UPK3B | c.48_50del p.L17del | In Frame Del (DEL) | VAF 10/38 reads (26%) | called by pindel, varscan2
- VAMP1 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- VRTN | c.716del p.P239Lfs*136 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- WDR19 | c.1867_1868del p.Q623Efs*10 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by pindel, varscan2
- ZFHX3 | c.2287del p.E763Sfs*61 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- ZNF175 | c.1824_1825del p.T610* | Frame Shift Del (DEL) | VAF 17/134 reads (13%) | called by mutect2, pindel, varscan2
- ZNF839 | c.1941del p.P648Lfs*17 (on ENST00000558850 / NM_001267827.1; = p.P764Lfs*17 on NM_018335.5) | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- ABLIM3 | c.534C>T p.C178= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV58641761; called by muse, mutect2, varscan2
- ACACB | c.6180G>A p.T2060= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs748417042, COSV58129598; called by muse, mutect2, varscan2
- ADAR | c.3420C>T p.D1140= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV52713614; called by muse, mutect2, varscan2
- ADARB2 | c.546G>A p.A182= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs748392221, COSV67219710; called by muse, mutect2, varscan2
- ADGRA3 | c.3246G>A p.T1082= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs769272862, COSV51561740; called by muse, mutect2, varscan2
- ADGRE5 | c.48G>A p.P16= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs765708033, COSV99662664; called by muse, varscan2
- AFF3 | c.3414C>T p.N1138= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs780887781, COSV57848841; called by muse, mutect2, varscan2
- ALS2CL | c.1500C>T p.T500= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV59670881; called by muse, mutect2, varscan2
- ANAPC1 | c.1842C>T p.T614= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs761627503, COSV61975196; called by muse, mutect2, varscan2
- ANKRD11 | c.2889C>T p.D963= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs139955323; ClinVar: likely benign; called by muse, mutect2, varscan2
- AP5B1 | c.792G>A p.A264= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1334070192, COSV57502641; called by muse, mutect2, varscan2
- APLP2 | c.1914C>T p.A638= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1362069978, COSV53839973; called by muse, mutect2, varscan2
- ARHGAP10 | c.1455C>T p.S485= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs372408519; called by muse, mutect2, varscan2
- ASB17 | c.261C>T p.L87= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs11811988, COSV52409902; called by muse, mutect2, varscan2
- ASL | c.762C>T p.S254= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as CM022319, COSV59188238; called by muse, mutect2, varscan2
- ASMT | c.366C>T p.D122= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs151095769, COSV67109654; called by muse, mutect2, varscan2
- ASMTL | c.168G>A p.G56= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs1419510252, COSV67243335; called by muse, mutect2, varscan2
- CAMSAP1 | c.1932C>T p.R644= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs773535330, COSV56720791; called by muse, mutect2, varscan2
- CARD19 | c.42G>A p.T14= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs770515947, COSV64935899; called by muse, mutect2, varscan2
- CBARP | c.642G>A p.T214= (on ENST00000382477; = p.T194= on NM_152769.3) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs779189297, COSV53068341; called by muse, mutect2, varscan2
- CCDC78 | c.516G>A p.A172= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs1434422837, COSV52401564; called by muse, mutect2, varscan2
- CCDC81 | c.601A>C p.R201= (on ENST00000445632 / NM_001156474.2; = p.R111= on NM_021827.4) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV53577516; called by muse, mutect2, varscan2
- CDKN2B | c.207C>T p.G69= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs769434878, COSV52805141; called by muse, mutect2, varscan2
- CFAP54 | c.5760G>A p.A1920= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs149195544, COSV61570320; called by muse, mutect2, varscan2
- COL27A1 | c.2457C>T p.P819= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs748462871, COSV61924158; called by muse, mutect2, varscan2
- CPA1 | c.285G>A p.S95= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs782095540, COSV50568133; called by muse, mutect2
- CSF1R | c.132C>T p.G44= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1443776257, COSV53832377; called by muse, mutect2, varscan2
- CWF19L2 | c.600G>A p.P200= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs773657776, COSV56510713; called by muse, mutect2
- CYP2S1 | c.192C>T p.Y64= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1239799106, COSV59505671; called by muse, mutect2, varscan2
- DCT | c.429C>T p.G143= | Silent (SNP) | VAF 37/191 reads (19%) | catalogued as rs755335828, COSV65468245; called by muse, mutect2, varscan2
- DHX16 | c.1797G>A p.V599= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV64563520; called by muse, mutect2, varscan2
- DPF2 | c.138C>T p.T46= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs139698375; called by muse, mutect2, varscan2
- DYRK1A | c.798G>A p.A266= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs774148181, CX160103, COSV58292982; called by muse, mutect2, varscan2
- EFEMP2 | c.927C>T p.C309= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs766494495, COSV57259616; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERN2 | c.1239C>T p.S413= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs572180599, COSV56832578; called by muse, mutect2, varscan2
- EVC | c.1437G>A p.P479= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs112861104; called by muse, mutect2, varscan2
- FER1L6 | c.792G>A p.A264= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as rs368591561; called by muse, mutect2, varscan2
- FGFR3 | c.1086C>T p.G362= (on ENST00000260795; = p.A312V on NM_000142.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs778617562, COSV53397224; called by muse, mutect2
- FLNC | c.4530C>T p.D1510= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs565243603, COSV57953381; called by muse, mutect2, varscan2
- GLYATL1 | c.405G>A p.T135= (on ENST00000317391 / NM_001354699.1; = p.T166= on NM_080661.4) | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs370872373; called by muse, mutect2, varscan2
- GPN2 | c.390A>G p.Q130= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs746292390, COSV64651847; called by muse, mutect2, varscan2
- GRIK2 | c.2295C>T p.G765= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs372392956; called by muse, mutect2, varscan2
- H3C2 | c.411A>G p.*137= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV52518260; called by muse, mutect2
- HHAT | c.1284C>T p.H428= | Silent (SNP) | VAF 36/239 reads (15%) | catalogued as rs117382486; called by muse, mutect2, varscan2
- HIF1A | c.975T>C p.Y325= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60188711; called by muse, mutect2, varscan2
- HOXD3 | c.816G>A p.P272= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV50879641; called by muse, mutect2
- HSF1 | c.759C>T p.Y253= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs781961875, COSV60047371; called by muse, mutect2, varscan2
- HSPG2 | c.8373C>T p.Y2791= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs753033341, COSV65970352; called by muse, mutect2, varscan2
- HTT | c.8388C>T p.D2796= | Silent (SNP) | VAF 31/248 reads (13%) | catalogued as rs769866904, COSV61859820; called by muse, mutect2, varscan2
- IFT52 | c.1287T>C p.S429= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV65974737; called by muse, mutect2, varscan2
- IGBP1 | c.843G>A p.P281= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs770539359, COSV60555897; called by muse, mutect2, varscan2
- IGF2R | c.4791T>C p.P1597= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV63627903; called by muse, mutect2, varscan2
- IL18RAP | c.231C>T p.N77= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs764677669, COSV51825194; called by muse, mutect2, varscan2
- IMPDH1 | c.1485G>A p.S495= (on ENST00000470772 / NM_001142573.2; = p.S581= on NM_000883.4) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs765536215, COSV100118807, COSV58315516; called by muse, mutect2, varscan2
- INSYN2A | c.324G>A p.S108= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs534565452, COSV99727242; called by muse, mutect2, varscan2
- IQCF2 | c.267G>A p.R89= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1023942628, COSV60761320; called by mutect2, varscan2
- IRAK2 | c.750C>T p.I250= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs199981706, COSV56530244; called by muse, mutect2, varscan2
- ITGB8 | c.504C>T p.S168= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs200718910; called by muse, mutect2, varscan2
- JAK1 | c.3039T>C p.S1013= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV53805923; called by muse, mutect2
- JCAD | c.3588G>A p.L1196= | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as rs1015742619, COSV64758831; called by muse, mutect2, varscan2
- KATNIP | c.705C>T p.G235= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1331391487, COSV55176991; called by muse, mutect2, varscan2
- KCNQ2 | c.366G>A p.S122= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100610035, COSV60432928; called by muse, mutect2, varscan2
- KCTD17 | c.600C>T p.N200= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as rs757067692, COSV63248848; called by muse, mutect2, varscan2
- KLHL3 | c.1416C>T p.Y472= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs776845721, COSV59051800; called by muse, mutect2, varscan2
- KSR2 | c.963C>T p.R321= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1025244189, COSV60366545; called by muse, mutect2
- LAMA1 | c.7650C>T p.I2550= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1197604032, COSV67534501; called by muse, mutect2, varscan2
- LDLR | c.1251C>T p.S417= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs763449261, COSV52942433; called by muse, mutect2, varscan2
- LILRA2 | c.729G>A p.Q243= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV52190058; called by muse, mutect2, varscan2
- LRRC61 | c.732G>A p.A244= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs748132818, COSV56230953; called by mutect2, varscan2
- MAGEA6 | c.387G>A p.P129= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as rs150153047, COSV61448703, COSV61449231; called by muse, mutect2, varscan2
- MBTPS1 | c.1623C>T p.N541= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs141003439; called by muse, mutect2, varscan2
- MFSD9 | c.642C>T p.L214= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs1265928091, COSV51493084; called by muse, mutect2
- MKI67 | c.2106T>A p.V702= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV64073595; called by muse, mutect2, varscan2
- MUC5B | c.2694C>T p.Y898= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs546384509, COSV71591092; called by muse, mutect2, varscan2
- MYH7B | c.5883G>A p.A1961= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs374941328; called by muse, mutect2, varscan2
- MYLK | c.2226C>T p.C742= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs757584912, COSV60607795; called by muse, mutect2, varscan2
- MYO1F | c.1215C>T p.F405= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as rs779481404, COSV57793386; called by muse, mutect2, varscan2
- MYO3A | c.3006C>T p.Y1002= | Silent (SNP) | VAF 34/192 reads (18%) | catalogued as rs1182938641, COSV56325341; called by muse, mutect2, varscan2
- MYOM1 | c.120C>T p.T40= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV55288590; called by muse, mutect2, varscan2
- NASP | c.1149G>A p.P383= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as rs761576032, COSV100601650; called by muse, mutect2, varscan2
- NCKAP5 | c.4110G>A p.L1370= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV58436820; called by muse, mutect2, varscan2
- NEURL4 | c.4113C>T p.C1371= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV59748343; called by muse, mutect2, varscan2
- NID2 | c.3048G>A p.P1016= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs764094695, COSV53494620; called by muse, mutect2, varscan2
- NLGN4X | c.1389C>T p.Y463= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1179387393, COSV52011546; called by muse, mutect2, varscan2
- NOXO1 | c.129C>T p.D43= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs926469931, COSV50191359; called by muse, mutect2, varscan2
- OR4A16 | c.777C>A p.P259= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs79231280, COSV59042499; called by muse, mutect2, varscan2
- OR8U1 | c.603C>A p.A201= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV56414992; called by muse, varscan2
- PADI2 | c.585C>T p.P195= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs746689551, COSV100970998, COSV64945612; called by muse, mutect2, varscan2
- PAN2 | c.3129G>A p.S1043= (on ENST00000425394 / NM_001127460.3; = p.S1039= on NM_014871.5) | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs758389894, COSV56264117, COSV56265309; called by muse, mutect2, varscan2
- PAPPA2 | c.618G>A p.A206= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as rs774718615, COSV62775809; called by muse, mutect2, varscan2
- PARP1 | c.2730G>A p.T910= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs756963125, COSV64689804; called by muse, mutect2, varscan2
- PCDHA5 | c.1722C>T p.G574= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV65350914; called by muse, mutect2
- PCDHA8 | c.1278C>T p.T426= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs1460884024, COSV65335785; called by muse, mutect2, varscan2
- PCDHGB2 | c.2103G>A p.V701= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV53922864; called by muse, mutect2, varscan2
- PDE7A | c.27A>G p.V9= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs928684739, COSV67523534; called by muse, mutect2
- PDZRN3 | c.2367G>A p.P789= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs200099704, COSV55195313; called by muse, mutect2, varscan2
- PEX1 | c.1170A>G p.G390= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs763167583, COSV50395964; called by muse, mutect2, varscan2
- PEX7 | c.654G>A p.A218= | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as rs1414537422, COSV100576492, COSV59247897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGLYRP2 | c.1461C>T p.T487= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV52992575; called by muse, mutect2
- PIK3C2B | c.3258C>T p.D1086= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs1246206905, COSV65810297; called by muse, mutect2, varscan2
- PKD1L1 | c.1182A>G p.S394= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV56961652; called by muse, mutect2, varscan2
- PLEC | c.2283C>T p.A761= (on ENST00000322810 / NM_201380.4; = p.A651= on NM_000445.5) | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs782547448, COSV59620041; called by muse, mutect2, varscan2
- PLXNB3 | c.1194C>T p.S398= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs782447682, COSV62796486; called by muse, mutect2, varscan2
- PPP1R13L | c.2193C>T p.F731= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs769470483, COSV62908079; called by muse, mutect2, varscan2
- PPP1R3A | c.288G>A p.T96= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs111896635; called by muse, mutect2, varscan2
- PRKACG | c.102C>T p.P34= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV55241378, COSV99598369; called by muse, mutect2, varscan2
- PROS1 | c.357C>T p.D119= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as CM128585, COSV62398147, COSV62399835; called by muse, mutect2, varscan2
- PTK2B | c.2580G>A p.P860= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs753172017, COSV100593454, COSV57752802; called by muse, mutect2, varscan2
- PTPRS | c.138G>A p.S46= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs140383630, COSV53611869; called by muse, mutect2, varscan2
- PTX4 | c.852C>T p.V284= (on ENST00000447419 / NM_001328608.2; = p.V279= on NM_001013658.1) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV53515147; called by muse, mutect2, varscan2
- RAB17 | c.87C>T p.S29= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs776807116, COSV52815528; called by muse, mutect2, varscan2
- RGS12 | c.966C>T p.D322= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as rs754481096, COSV60903361; called by muse, mutect2, varscan2
- RHOBTB2 | c.69C>T p.N23= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs762585773, COSV52570261; called by muse, mutect2, varscan2
- RUFY1 | c.1689C>T p.R563= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs199910786, COSV60159127; called by muse, mutect2, varscan2
- RXRA | c.1017C>T p.S339= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs373205831; called by muse, mutect2, varscan2
- RYR3 | c.14127C>T p.D4709= (on ENST00000389232; = p.D4710= on NM_001036.6) | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs369078948; ClinVar: likely benign; called by muse, mutect2, varscan2
- SALL3 | c.3243C>T p.P1081= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1040213150, COSV73305912; called by muse, mutect2, varscan2
- SAMM50 | c.690C>T p.G230= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs771300763, COSV63109593; called by muse, mutect2
- SEC14L1 | c.1071G>A p.A357= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs370893885; called by muse, mutect2, varscan2
- SEMA6C | c.801C>T p.G267= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs377555884; called by muse, mutect2, varscan2
- SERPINB4 | c.894G>A p.T298= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs776882459, COSV61984620; called by muse, mutect2, varscan2
- SEZ6L2 | c.2421C>T p.G807= (on ENST00000308713 / NM_001114099.3; = p.G737= on NM_012410.4) | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs931025696, COSV58098441; called by muse, mutect2, varscan2
- SHCBP1 | c.729T>C p.L243= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV57646857; called by muse, mutect2, varscan2
- SLC39A7 | c.1221C>T p.G407= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as rs1284252343, COSV63002430; called by muse, mutect2
- SLCO4A1 | c.312C>T p.G104= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV53890049; called by muse, mutect2
- SMARCAL1 | c.1464C>T p.S488= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs139469074; called by muse, mutect2, varscan2
- SNX31 | c.87C>T p.D29= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV61262570; called by muse, mutect2, varscan2
- SPON2 | c.663G>A p.P221= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs545107781, COSV52054642; called by mutect2, varscan2
- SPTAN1 | c.5697C>T p.G1899= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs150960451; called by muse, mutect2, varscan2
- SPTBN1 | c.6321G>A p.T2107= | Silent (SNP) | VAF 30/200 reads (15%) | catalogued as rs150684675; called by muse, mutect2, varscan2
- ST14 | c.549G>A p.P183= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as rs774428715, COSV53832485; called by muse, mutect2, varscan2
- SWAP70 | c.585T>G p.T195= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV59663187; called by muse, mutect2, varscan2
- SYNJ2 | c.990G>A p.T330= | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as rs750486579, COSV62896419; called by muse, mutect2, varscan2
- TAF15 | c.1485T>C p.G495= (on ENST00000605844 / NM_139215.3; = p.G492= on NM_003487.4) | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- TBC1D14 | c.249G>A p.A83= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs780068290, COSV68985190; called by muse, mutect2, varscan2
- TDO2 | c.69C>T p.S23= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs200196655, COSV72232506; called by muse, mutect2
- TEPSIN | c.516C>T p.H172= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1274903992, COSV56142319, COSV56144258; called by muse, mutect2
- THBS2 | c.2211C>T p.G737= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs780517126, COSV64678052; called by muse, mutect2, varscan2
- TMEM132E | c.2019G>A p.V673= (on ENST00000321639; = p.V763= on NM_001304438.2) | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as COSV58695875; called by muse, mutect2, varscan2
- TNFRSF1A | c.1176C>T p.N392= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV50599238; called by muse, mutect2, varscan2
- TNR | c.669C>T p.S223= | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as rs1032289234, COSV54878193; called by muse, mutect2, varscan2
- TNRC6C | c.75C>T p.G25= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs138478334; called by muse, mutect2, varscan2
- TRAV36DV7 | c.84C>T p.S28= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs954258510; called by muse, mutect2, varscan2
- TRIM16L | c.882C>T p.G294= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs375964173, COSV67459272; called by muse, mutect2, varscan2
- TRIM36 | c.1626A>T p.G542= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV56689468; called by muse, mutect2, varscan2
- TRIM67 | c.978C>T p.C326= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV64158542; called by muse, mutect2
- TRIO | c.8559C>T p.V2853= | Silent (SNP) | VAF 54/314 reads (17%) | catalogued as rs754497690, COSV59988552, COSV59991468; called by muse, mutect2, varscan2
- TTC14 | c.1020C>T p.N340= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV56010339; called by muse, mutect2
- TTC39B | c.1878G>A p.P626= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs370022194; called by muse, mutect2, varscan2
- TTN | c.20563A>C p.R6855= (on ENST00000591111; = p.R5928= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV59969064; called by muse, mutect2
- TULP1 | c.1140G>A p.T380= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs145986072; called by muse, mutect2, varscan2
- UBE2O | c.2712C>T p.S904= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs139988070; called by muse, mutect2, varscan2
- USP49 | c.654C>T p.D218= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1446342409, COSV51895884; called by muse, mutect2
- VIRMA | c.5263T>C p.L1755= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV52583566; called by muse, mutect2, varscan2
- VPS13A | c.3177G>A p.S1059= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs756705615, COSV62427308; called by muse, mutect2, varscan2
- VWF | c.5442C>T p.A1814= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs757527506, COSV54615902; called by muse, mutect2, varscan2
- XIRP1 | c.1140C>T p.S380= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as rs768703924, COSV61137721; called by muse, mutect2, varscan2
- ZFYVE28 | c.2346G>A p.A782= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as rs549587391, COSV52109504; called by muse, mutect2, varscan2
- ZNF398 | c.819G>A p.S273= (on ENST00000475153 / NM_170686.3; = p.S102= on NM_020781.4) | Silent (SNP) | VAF 23/179 reads (13%) | catalogued as rs201966256, COSV60064918; called by muse, mutect2, varscan2
- ZNF443 | c.2001T>C p.H667= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV56891017; called by muse, varscan2
- ZNF516 | c.2820C>T p.G940= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs753080203, COSV71586863; called by muse, mutect2, varscan2
- ZNF835 | c.681C>T p.C227= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1173756332, COSV73379339; called by muse, mutect2, varscan2
- ZNF880 | c.849T>A p.L283= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101424959, COSV69905974; called by muse, mutect2, varscan2
- ZNF91 | c.1959T>C p.T653= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV56082749; called by muse, mutect2, varscan2
- ZRANB2 | c.531C>T p.D177= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs767389252, COSV54671358; called by muse, mutect2
- ANK3 | c.12596-290C>T | Intron (SNP) | VAF 11/127 reads (9%) | catalogued as COSV55051037; called by muse, mutect2
- DST | c.4296+4078G>A | Intron (SNP) | VAF 10/54 reads (19%) | catalogued as COSV55006347; called by muse, mutect2, varscan2
- DUSP13 | c.*259C>T | 3'UTR (SNP) | VAF 25/106 reads (24%) | catalogued as rs536279604, COSV57813844; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445865 C>T | 3'Flank (SNP) | VAF 11/62 reads (18%) | catalogued as rs749716596; called by muse, mutect2, varscan2
- KLRA1P | n.142T>G | RNA (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- LIM2 | c.175+96C>T | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as rs779361558, COSV55740642; called by muse, mutect2
- OBSCN | c.11659+4373C>T | Intron (SNP) | VAF 18/105 reads (17%) | catalogued as rs773990433, COSV52758485; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.-72del | 5'UTR (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- PDE4D | c.455+124719C>T | Intron (SNP) | VAF 12/113 reads (11%) | catalogued as COSV58949893; called by muse, mutect2, varscan2
- SNORD114-20 | n.25C>T | RNA (SNP) | VAF 20/134 reads (15%) | catalogued as rs753455560; called by muse, mutect2
- TRIP12 | c.99-894T>C | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as COSV52261437; called by muse, mutect2, varscan2
- TTN | c.10361-3964del | Intron (DEL) | VAF 8/70 reads (11%) | catalogued as rs1560961746; called by mutect2, pindel, varscan2
- TUBB7P | n.233C>T | RNA (SNP) | VAF 34/161 reads (21%) | catalogued as rs531124571; called by muse, mutect2, varscan2
